TCGA case TCGA-44-4112 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/68b86559-38b2-41f2-b66e-c3c2b628b14d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 808 days (2.2 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.5 years (22,106 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 78 days; Days to treatment end: 142 days; Number of cycles: 4; Treatment dose: 660 mg; Prescribed dose: 165; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pemetrexed Disodium; Treatment intent type: Adjuvant; Days to treatment start: 78 days; Days to treatment end: 142 days; Number of cycles: 4; Treatment dose: 4,400 mg; Prescribed dose: 1100; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Progressive Disease; Days to treatment start: 654 days (1.8 years); Days to treatment end: 675 days (1.8 years); Treatment dose: 3,500 cGy; Course number: 1; Number of fractions: 14; Treatment anatomic sites: Distant Site.
2. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 62.2 years (22,725 days); Days to diagnosis: 619 days (1.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 619 days (1.7 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Radiation Therapy, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS to Locoregional Site.

Follow-up (7 entries)
- Days to follow up: 370 days (1.0 years); Disease response: Tumor Free.
- Day 619 (post initial treatment): Progression or recurrence: Yes.
- Days to follow up: 722 days (2.0 years); Disease response: With Tumor.
- Days to follow up: 808 days (2.2 years); Disease response: With Tumor.
- ECOG performance status: 0; Timepoint: Adjuvant Therapy.
- Karnofsky performance status: 70; Timepoint: Other.
- Follow-up contact recording only the day: day 141.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 30; Tobacco smoking onset year: 1972; Tobacco smoking quit year: 1992.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-44-4112-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Initial weight: 220 mg; Longest dimension: 2; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-44-4112-01A-01-TS1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 35.
  Slide TCGA-44-4112-01A-01-BS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
  Slide TCGA-44-4112-01A-03-TSC: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 5.
- Sample TCGA-44-4112-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide TCGA-44-4112-01B-05-BS5: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 2; Percent necrosis: 2; Percent stromal cells: 31; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 2.
  Slide TCGA-44-4112-01B-05-TS5: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 1; Percent necrosis: 2; Percent stromal cells: 27; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide TCGA-44-4112-01B-06-BS6: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 2; Percent necrosis: 1; Percent stromal cells: 27; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 2.
- Sample TCGA-44-4112-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-44-4112-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-44-4112-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 520 mg; Longest dimension: 1.5; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-44-4112-11A-02-TSB: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 0.
  Slide TCGA-44-4112-11A-03-TSC: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 40.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; KRAS gene analysis indicator: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 1; Pharmaceutical therapy drug name: Alimta.
- Radiation treatment: Therapy regimen: Progression.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: New tumor event diagnosis indicator: Yes; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No; New tumor event surgery met: Yes; Treatment outcome at TCGA followup: Stable Disease.
- Follow-up form 3: New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 808 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 808 days; disease-free interval: event (new tumor event after initially disease-free), 619 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 619 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-44-4112-01A-01D-A273-01): tumor purity 0.57, ploidy 2.13, whole-genome doublings 0.
